Somatic mutation profile of tumor specimen faadb553-9437-42cb-b469-498d67 (aliquot faadb553-9437-42cb-b469-498d67_D6_1) from CPTAC case 11BR013, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.9 years (25,549 days).
Specimen faadb553-9437-42cb-b469-498d67: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7406b44e-05d6-4b47-8544-3b2ef84f9032.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 51de6425-8c2f-486c-8073-2d60fa (Blood Derived Normal), aliquot 51de6425-8c2f-486c-8073-2d60fa_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9530d5c5-9722-40bd-9284-1953e6dccc8c

The open-access MAF lists 83 somatic variants for this specimen: 57 protein-altering or splice-affecting, 14 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 14, Intron 5, RNA 3, 5'UTR 2, Nonsense Mutation 2, In Frame Del 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 60/183 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.5698C>G p.L1900V | Missense Mutation (SNP) | VAF 86/242 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV101329880, COSV70026424; called by muse, mutect2, varscan2
- ADGRA2 | c.2609C>G p.P870R | Missense Mutation (SNP) | VAF 171/665 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV99604644; called by muse, mutect2, varscan2
- APOBEC3G | c.899C>G p.S300* | Nonsense Mutation (SNP) | VAF 70/159 reads (44%) | catalogued as COSV68470252; called by muse, mutect2, varscan2
- ARHGAP23 | c.899C>A p.A300E | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as rs904903530; called by muse, mutect2
- ASPM | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV54135434; called by muse, mutect2
- CALHM2 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 123/316 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.289); catalogued as rs777219053, COSV99588370; called by muse, mutect2, varscan2
- CCDC71 | c.1002_1028del p.V335_K343del | In Frame Del (DEL) | VAF 148/438 reads (34%) | catalogued as rs773541022; called by mutect2, varscan2
- CNTN4 | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs761965189, COSV61872783; called by muse, mutect2, varscan2
- COL4A3 | c.4466C>T p.T1489I | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs200818438, COSV101170383; called by muse, mutect2, varscan2
- CROCC | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 204/614 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs762827216; called by muse, mutect2, varscan2
- CRYBG2 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 82/354 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs767259243, COSV100366840; called by muse, mutect2, varscan2
- CRYGC | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 93/263 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as rs764781357; called by muse, mutect2, varscan2
- CTAGE15 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 175/466 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.803); catalogued as COSV69482068; called by muse, mutect2, varscan2
- CYBA | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1247886457; called by muse, mutect2, varscan2
- DCTN4 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1287970521; called by muse, mutect2, varscan2
- DNAH6 | c.12020G>A p.R4007Q | Missense Mutation (SNP) | VAF 79/199 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367739383; called by muse, mutect2, varscan2
- KCNH8 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376188228; called by muse, mutect2
- KCNH8 | c.1709C>G p.S570C | Missense Mutation (SNP) | VAF 10/323 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV60463334; called by muse, mutect2
- KLRC4 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV58671664; called by muse, mutect2, varscan2
- LPA | c.5256C>G p.H1752Q | Missense Mutation (SNP) | VAF 101/265 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs369329857; called by muse, mutect2, varscan2
- MAP2K1 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 108/316 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.188); catalogued as COSV61073567; called by muse, mutect2, varscan2
- MEN1 | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 184/304 reads (61%) | catalogued as CM981274, COSV53641874, COSV53647250; called by muse, mutect2, varscan2
- NUTM2G | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 169/712 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs528848656; called by muse, mutect2, varscan2
- OR56B1 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100402686; called by muse, mutect2
- P2RY1 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as rs1406416376, COSV59309293; called by muse, mutect2, varscan2
- PCDHB8 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 455/2252 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs782031855, COSV50788123, COSV99177493; called by muse, mutect2, varscan2
- PGAP6 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs370004240; called by muse, mutect2, varscan2
- SPTB | c.4855G>A p.A1619T | Missense Mutation (SNP) | VAF 192/555 reads (35%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.513); catalogued as rs537141390; called by muse, mutect2, varscan2
- TIGD5 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 66/1120 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); catalogued as rs747077737, COSV55306184; called by muse, mutect2
- ZNF831 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs766314897; called by muse, mutect2, varscan2
- BRS3 | c.1048G>T p.A350S | Missense Mutation (SNP) | VAF 94/301 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- C2CD4A | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- CD34 | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- CDIPT | c.44G>C p.G15A | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEACAM5 | c.2051C>T p.S684L | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- CEMIP2 | c.3349A>G p.R1117G | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CEP250 | c.3102G>C p.Q1034H | Missense Mutation (SNP) | VAF 11/215 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2
- CLEC14A | c.425G>C p.R142T | Missense Mutation (SNP) | VAF 50/492 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2
- CUL4B | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- DNAAF2 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 188/520 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ELOF1 | c.152C>G p.T51S | Missense Mutation (SNP) | VAF 103/255 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EPHA6 | c.826A>G p.K276E | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM120C | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYOC | c.225G>C p.Q75H | Missense Mutation (SNP) | VAF 25/354 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NAA30 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2
- PAPLN | c.887A>T p.H296L (on ENST00000554301; = p.H269L on NM_173462.4) | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2
- PLEKHH1 | c.1337G>A p.C446Y | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SLC30A9 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SRRM2 | c.2861C>T p.S954F | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TEP1 | c.3208A>G p.I1070V | Missense Mutation (SNP) | VAF 111/258 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRGC1 | c.349C>G p.P117A | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBXN2A | c.190A>T p.N64Y | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- WDFY3 | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- WDTC1 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XPO1 | c.3105G>T p.L1035F | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.933); called by muse, mutect2
- ZNF638 | c.1712C>T p.S571L | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BAHCC1 | c.5283C>G p.G1761= | Silent (SNP) | VAF 56/349 reads (16%) | called by muse, mutect2, varscan2
- C2orf81 | c.1212G>A p.P404= | Silent (SNP) | VAF 58/142 reads (41%) | called by muse, mutect2, varscan2
- CAVIN3 | c.666G>A p.P222= | Silent (SNP) | VAF 76/118 reads (64%) | called by muse, mutect2, varscan2
- CCNL1 | c.96G>T p.T32= | Silent (SNP) | VAF 127/356 reads (36%) | catalogued as rs1225635202; called by muse, mutect2, varscan2
- DISP3 | c.357C>T p.F119= | Silent (SNP) | VAF 77/167 reads (46%) | catalogued as COSV99608508; called by muse, mutect2, varscan2
- GLTPD2 | c.60C>T p.L20= | Silent (SNP) | VAF 18/248 reads (7%) | called by muse, mutect2
- MZT2B | c.120G>A p.L40= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs1477324998; called by mutect2, varscan2
- NEB | c.8814C>T p.D2938= | Silent (SNP) | VAF 54/162 reads (33%) | called by muse, mutect2, varscan2
- PCDHAC1 | c.1359C>T p.F453= | Silent (SNP) | VAF 134/341 reads (39%) | catalogued as rs267600404; called by muse, mutect2, varscan2
- PCDHB12 | c.1710G>A p.A570= | Silent (SNP) | VAF 96/1510 reads (6%) | catalogued as COSV99507090; called by muse, mutect2
- SLC4A7 | c.3486A>G p.Q1162= | Silent (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- STX16 | c.96C>A p.I32= | Silent (SNP) | VAF 42/245 reads (17%) | called by muse, mutect2, varscan2
- SWI5 | c.168C>T p.L56= | Silent (SNP) | VAF 46/152 reads (30%) | catalogued as rs745352991, COSV60791980; called by muse, mutect2, varscan2
- WNK4 | c.3186C>T p.G1062= | Silent (SNP) | VAF 106/263 reads (40%) | catalogued as rs1218077406; called by muse, mutect2, varscan2
- BAGE2 | n.110T>C | RNA (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2
- GRXCR1 | c.-31C>T | 5'UTR (SNP) | VAF 12/171 reads (7%) | called by muse, mutect2
- KRT8 | c.-17C>T | 5'UTR (SNP) | VAF 45/149 reads (30%) | catalogued as rs1257167042; called by muse, mutect2, varscan2
- MIR374B | n.6G>A | RNA (SNP) | VAF 10/109 reads (9%) | called by muse, mutect2
- MYOF | c.*21C>G | 3'UTR (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- PKP3 | c.2358+11C>T | Intron (SNP) | VAF 113/208 reads (54%) | catalogued as rs111439391; called by muse, mutect2, varscan2
- RFK | chr9:76399169 G>A | 5'Flank (SNP) | VAF 229/607 reads (38%) | catalogued as rs539624045; called by muse, mutect2, varscan2
- RIPK3 | c.471+63C>T | Intron (SNP) | VAF 40/102 reads (39%) | catalogued as rs760312244; called by muse, mutect2
- SIRPA | c.1266+12G>T | Intron (SNP) | VAF 33/149 reads (22%) | called by muse, mutect2, varscan2
- SSPOP | n.9013C>T | RNA (SNP) | VAF 39/349 reads (11%) | called by muse, mutect2, varscan2
- TMC6 | c.1811+47G>A | Intron (SNP) | VAF 36/507 reads (7%) | called by muse, mutect2
- TMC6 | c.1715+149_1715+150insTT | Intron (INS) | VAF 63/227 reads (28%) | called by mutect2, pindel, varscan2
